TCGA case TCGA-D1-A16D — Uterine Corpus Endometrial Carcinoma (TCGA-UCEC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Corpus uteri; Tissue source site: Mayo Clinic. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5693302a-4548-4c0b-8725-0cb7c67bc4f8

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 49 years; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; ICD-10 code: C54.1; Tissue or organ of origin: Endometrium; Site of resection or biopsy: Endometrium; Classification of tumor: primary; Age at diagnosis: 49.1 years (17,933 days); Year of diagnosis: 2008; Method of diagnosis: Biopsy; FIGO stage: Stage IC; FIGO staging edition year: 1995; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Days to last follow up: 1,141 days (3.1 years).
   Pathology details: Lymph node involved site: Pelvis, NOS; Lymph nodes positive: 0; Lymph nodes tested: 34.
   Pathology details: Consistent pathology review: Yes; Percent tumor invasion: 86.
   Pathology details: Lymph node involved site: Aortic; Lymph nodes positive: 0; Lymph nodes tested: 0.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 62 days; Days to treatment end: 232 days; Number of cycles: 6; Prescribed dose: 2; Prescribed dose units: AUC; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 62 days; Days to treatment end: 232 days; Number of cycles: 6; Treatment dose: 2,150 mg; Prescribed dose: 50; Prescribed dose units: mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, Implants; Treatment intent type: Adjuvant; Days to treatment start: 96 days; Days to treatment end: 104 days; Treatment dose: 2,100 cGy; Course number: 1; Number of fractions: 3; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Surgery, Open; Initial disease status: Initial Diagnosis.
   Recorded as not given: Pharmaceutical Therapy, NOS (Tamoxifen), prior to diagnosis.

Follow-up (3 entries)
- Days to follow up: 908 days (2.5 years); Disease response: Tumor Free.
- Days to follow up: 1,141 days (3.1 years); Disease response: Tumor Free.
- Peritoneal washing results: Negative; Timepoint: Initial Diagnosis.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Hormonal replacement therapy status: No; Menopause status: Perimenopausal; Number of pregnancies: 0; Pregnancy outcome: Full Term Birth, NOS; Risk factors: Diabetes, NOS / Hypertension.
- Timepoint category: Initial Diagnosis; Weight: 151 kg; Height: 164 cm; BMI: 56.1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D1-A16D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 130 mg.
  Slide TCGA-D1-A16D-01A-01-TSA: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 40; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 8; Percent neutrophil infiltration: 12.
- Sample TCGA-D1-A16D-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-D1-A16D-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Peri (6-12 months since last menstrual period); History neoadjuvant treatment: No; Tumor status: Tumor free; Submitted tumor site: Endometrial; Histologic diagnosis: Endometrioid endometrial adenocarcinoma; Method initial path diagnosis: Office Endometrial Biopsy; Surgical approach at diagnosis: open.
- Follow-up form: History menopausal hormone therapy: No, I have never taken menopausal hormone therapy; History tamoxifen use: Never Used; Hypertension diagnosis: Yes; Diabetes diagnosis indicator: Yes; Pregnancies full term count: 0; History colorectal cancer: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.
- Drug treatment 1: Regimen number: 1; Pharmaceutical therapy drug name: Taxol.
- Drug treatment 1, Route of administrations: Route of administration: IV.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,141 days; disease-specific survival: no event (censored), 1,141 days; disease-free interval: no event (censored), 1,141 days; progression-free interval: no event (censored), 1,141 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-D1-A16D-01): tumor purity 0.6, ploidy 2, whole-genome doublings 0 (call status: maf_call).
